TARGET case TARGET-30-PASEYW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f3596946-508d-57b4-9fcc-bae3600e3cfd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C72.0; Tissue or organ of origin: Spinal cord; Classification of tumor: primary; Age at diagnosis: 1.9 years (704 days); Year of diagnosis: 2008; Days to last follow up: 3,686 days (10.1 years); Cog neuroblastoma risk group: Low Risk; Inpc grade: Differentiating; INSS stage: Stage 2A; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 250 days; Days to first event: 250 days; First event: Relapse.
- Days to follow up: 3,686 days (10.1 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASEYW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASEYW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3686
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.16
- Histology: Favorable
- MKI: Low
- ICDO Description: Spinal cord Cervical cord Conus medullaris Filum terminal
- Site of Relapse: Primary site
